Somatic mutation profile of tumor specimen MP2PRT-PAVVIS-TMP1-A (aliquot MP2PRT-PAVVIS-TMP1-A-1-0-D-A81Q-36) from MP2PRT case MP2PRT-PAVVIS, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.8 years (1,018 days).
Specimen MP2PRT-PAVVIS-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 69d08a07-c2bb-4c90-ab62-660b52ceecf6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVVIS-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVVIS-NB1-A-1-0-D-A81Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9401c36b-c4a4-4cd7-bfdc-c4cf109a0c0c

The open-access MAF lists 4 somatic variants for this specimen: 1 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 2, Missense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PLEKHO1 | c.124_128delinsCCCCC p.K42_N43delinsPP | Missense Mutation (ONP) | VAF 38/381 reads (10%) | called by mutect2*, pindel
- KCNQ5 | c.543T>A p.S181= | Silent (SNP) | VAF 41/347 reads (12%) | called by muse, mutect2, varscan2
- PRUNE2 | c.8991C>T p.I2997= | Silent (SNP) | VAF 36/181 reads (20%) | called by muse, mutect2, varscan2
- ACSL6 | c.993+69del | Intron (DEL) | VAF 37/209 reads (18%) | called by pindel*, varscan2
